Gene-level copy-number profile of tumor specimen TCGA-37-A5EM-01A from TCGA case TCGA-37-A5EM, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage II; Age at diagnosis: 49.3 years (18,011 days).
Specimen TCGA-37-A5EM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.8bfc4ebe-d201-4212-9c80-6adc4632bdaf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-37-A5EM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS.
https://portal.gdc.cancer.gov/files/04a36294-6fa3-4dbb-b5e9-1884ae10a839

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 2: 7,835; copy number 3: 13,021; copy number 4: 24,041; copy number 5: 7,648; copy number 6: 3,598; copy number 7: 2,450; copy number 9: 1; copy number 11: 27; copy number 12: 645; copy number 14: 329; copy number 15: 10; copy number 17: 8; copy number 19: 51; copy number 20: 4; copy number 21: 26; copy number 23: 21; copy number 24: 39; copy number 27: 25; copy number 32: 7; copy number 34: 24.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:131,423,921–131,796,983, 2 genes (within-gene range 0–4): RAPGEF6, AC008695.1.
- chr5:131,641,714–131,797,063, 2 genes (within-gene range 0–4): FNIP1, ACTBP4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,217 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:162,486,541–198,222,513, 645 genes, copy number 12 (broad region; genes not listed).
- chr6:905,445–1,101,400, 3 genes, copy number 27 (within-gene range 4–27): AL356130.1, LINC01622, AL033381.2.
- chr6:1,623,806–2,640,001, 10 genes, copy number 24 (within-gene range 4–24): GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1, AL359852.2, AL359852.1, LINC02521, LINC01600.
- chr6:2,765,393–2,972,165, 8 genes, copy number 21 (within-gene range 4–21): WRNIP1, SERPINB1, SERPINB9P1, MIR4645, SERPINB9, AL133351.2, AL133351.1, SERPINB6.
- chr6:4,304,942–4,583,871, 1 gene, copy number 14 (within-gene range 3–14): AL162718.1.
- chr6:4,381,211–4,530,008, 5 genes, copy number 14: AL162718.3, RNA5SP202, AL162718.2, LINC02533, AL133393.1.
- chr6:5,291,030–5,458,075, 2 genes, copy number 19: AL121978.1, AL021328.1.
- chr6:5,817,421–6,622,771, 11 genes, copy number 23 (within-gene range 4–23): AL136968.1, AL136307.1, RN7SL221P, PKMP5, NRN1, F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1.
- chr6:6,901,022–6,918,715, 1 gene, copy number 21: AL158817.1.
- chr6:7,726,099–9,294,133, 15 genes, copy number 17–32: BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1, AL137220.1.
- chr6:10,511,036–10,514,546, 1 gene, copy number 24: AL139039.3.
- chr6:10,886,831–13,287,843, 31 genes, copy number 14–24 (within-gene range 4–24): SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2, HIVEP1, EDN1, SUMO2P12, RN7SKP293, RPL15P3, LINC02530, PHACTR1.
- chr6:13,357,830–15,522,042, 33 genes, copy number 14–27 (within-gene range 4–27): GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P.
- chr6:16,129,086–16,761,491, 10 genes, copy number 23 (within-gene range 5–23): MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1, ATXN1.
- chr6:17,381,367–17,582,305, 4 genes, copy number 20: AL034372.1, CAP2, RPL7P26, SUMO2P13.
- chr6:17,953,572–22,675,493, 55 genes, copy number 19–34: AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2.
- chr11:69,909,184–70,436,584, 21 genes, copy number 11: AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 11: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:71,382,601–71,423,423, 1 gene, copy number 9 (within-gene range 4–9): ACTE1P.
- chr19:28,435,388–28,727,680, 1 gene, copy number 19 (within-gene range 5–19): AC005394.2.
- chr19:28,491,864–28,632,728, 1 gene, copy number 19 (within-gene range 5–19): AC005394.1.
- chr19:28,602,379–38,618,882, 352 genes, copy number 14–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
